Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A59Z, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A59Z-01A (Primary Tumor).

[page 1 of 3]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) RIGHT AND LEFT PELVIC LYMPH NODE:
Two lymph nodes, no tumor identified (0/2).
- (B) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

GROSS DESCRIPTION

- (A) RIGHT AND LEFT PELVIC LYMPH NODE - Adipose tissue (5.0 x 5.0 x 1.5 cm). Two lymph nodes are identified (4.5 x 1.5 x 0.8 cm and 7.0 x 1.5 x 1.0 cm).
SECTION CODE: A1-A3, one lymph node serially sectioned; A4-A8, one lymph node serially sectioned.
- (B) PROSTATE AND SEMINAL VESICLES - Supplemental report to follow.

CLINICAL HISTORY

Prostate.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined b
specifically cleared or approved by the U.S. Food and Drug Administration."

these tests have not been

Start of ADDENDUM

ICD-O-3

Path: Adenocarcinoma NOS 8140/3

CCCF: Adenocarcinoma
Acinar Type 8550/3

Site: Prostate NOS C61.9

Gr. 1/18/13

[page 2 of 3]
ADDENDUM

This modified report is being issued to provide additional information/results.

DIAGNOSIS

- (B) PROSTATE AND SEMINAL VESICLES:
PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (4+3). (SEE COMMENT)
TUMOR CONFINED TO THE PROSTATE.
MARGINS OF RESECTION FREE OF TUMOR.
PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH-GRADE.
Right and left seminal vesicles, no tumor present.
Segments of right and left vasa deferentia, no tumor present.

COMMENT

The prostate gland contains two foci of prostatic adenocarcinoma. Both tumor foci are located in the peripheral zone. The dominant tumor focus is located in the left anterolateral, left lateral, left posterolateral, left posterior, mid posterior and right posterior peripheral zone. This tumor focus measures 2.0 x 1.5 cm in the largest cross-sectional dimension and it is present in the three cross sections of the prostate, extensively in the apex and focally in the base region. The second tumor focus is located in the right lateral peripheral zone. This tumor focus measures 0.2 x less than 0.1 cm in the largest cross-sectional dimension and it is present in one cross section. Both tumor foci are confined to the prostate. The margins of resection are free of tumor.

GROSS DESCRIPTION

- (B) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles, and attached segments of right and left vasa deferentia.

The prostate gland (3.6 x 4.0 x 5.1 cm, 35 grams, post fixation) has the usual shape. The soft tissue present along left posterolateral aspect of the prostate appears more abundant than along the right side. A nodule is palpated on the left base region. Serial cross sections after fixation demonstrate a firm area consistent with tumor in the left peripheral zone of the three cross sections of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: B1, B2, base of right seminal vesicle and right vas deferens; B3, B4, base of left seminal vesicle and left vas deferens; B5, prostatic base, right border; B6-B8, prostatic base, right posterior border; B9-B16, prostatic base, central portion; B17, prostatic base, left border; B18-B20, prostatic base, left posterior border; B21, B22, apex anterior; B23, B24, apex left; B25-B27, apex posterior; B28, B29, apex right; B30, detached portions of margin of resection according to the specimen

[page 3 of 3]
[REDACTED]

radiograph; B31-B42, sections of the three cross sections of the prostate according to the specimen radiograph.
The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Orange ink (B33, 34, 37, 38 and 42) denotes surfaces that do not represent the true margin of resection.

SNOMED CODES

[REDACTED]

Released by:

-----END OF REPORT-----

Criteria	12/10/12	Yes	No
I-PAA Discrepancy			✓

Source: NCI Genomic Data Commons file 60784f8b-392f-4678-8839-cffd39343da2 (TCGA-KK-A59Z.DDF6F24F-4406-49EE-9EE0-7129D8544677.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).